Somatic mutation profile of tumor specimen HCM-WCMC-0789-C34-01A (aliquot HCM-WCMC-0789-C34-01A-20D-A87L-36) from HCMI case HCM-WCMC-0789-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA2; Tumor grade: G2; Age at diagnosis: 83.6 years (30,550 days).
Specimen HCM-WCMC-0789-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14c3b4ef-127e-4880-b199-ceaf25a23c3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0789-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0789-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbd89884-5791-430d-a247-41e4cca722ec

The open-access MAF lists 309 somatic variants for this specimen: 221 protein-altering or splice-affecting, 85 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 85, Nonsense Mutation 18, Frame Shift Del 5, Intron 1, 3'Flank 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 73/346 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACIN1 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 45/299 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs769850217; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4454C>G p.A1485G | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.149); catalogued as rs750268074, COSV54471471; called by muse, mutect2, varscan2
- ADCK1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 13/333 reads (4%) | catalogued as rs1479461067; called by muse, mutect2
- ADGRE1 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.51); catalogued as COSV51679163; called by muse, varscan2
- ADGRL3 | c.2498G>A p.G833E (on ENST00000506720 / NM_001322402.2; = p.G765E on NM_015236.6) | Missense Mutation (SNP) | VAF 70/403 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.925); catalogued as rs557402887; called by muse, mutect2, varscan2
- AGPAT1 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.371); catalogued as rs767772319; called by muse, mutect2, varscan2
- BCL2L11 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 76/588 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs777425286; called by muse, mutect2, varscan2
- C12orf40 | c.23+1del | Frame Shift Del (DEL) | VAF 51/365 reads (14%) | catalogued as COSV61132520; called by mutect2, varscan2
- C16orf87 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 52/286 reads (18%) | catalogued as rs754738913, COSV99587569; called by muse, mutect2, varscan2
- CAMK2G | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1279584071; called by muse, mutect2, varscan2
- CAND2 | c.2750C>G p.S917* (on ENST00000456430 / NM_001162499.2; = p.S824* on NM_012298.3) | Nonsense Mutation (SNP) | VAF 48/348 reads (14%) | catalogued as COSV55990716; called by muse, mutect2, varscan2
- CAPN14 | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV67290255; called by muse, mutect2, varscan2
- CCDC154 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs561677923, COSV101209693, COSV101209706; called by muse, mutect2, varscan2
- CDKL4 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.348); catalogued as COSV101115558; called by muse, mutect2, varscan2
- CHEK2 | c.1378C>G p.L460V (on ENST00000382580 / NM_001005735.2; = p.L417V on NM_007194.4) | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100101286; called by muse, varscan2
- CMKLR1 | c.379G>A p.V127I (on ENST00000312143 / NM_001142344.2; = p.V125I on NM_004072.3) | Missense Mutation (SNP) | VAF 61/410 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs374487323; called by muse, mutect2, varscan2
- CPS1 | c.1391C>A p.P464Q | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826143; called by mutect2, varscan2
- CSMD1 | c.9483C>G p.I3161M (on ENST00000520002; = p.I3160M on NM_033225.6) | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.266); catalogued as COSV59327086; called by muse, mutect2
- DDX23 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 41/389 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as rs1158425469; called by muse, mutect2, varscan2
- DDX4 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.615); catalogued as COSV61757771; called by muse, mutect2, varscan2
- DIO3 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV63773899; called by muse, mutect2, varscan2
- ELAPOR1 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV64041099; called by muse, mutect2, varscan2
- EMP2 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 72/392 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); catalogued as COSV63995963; called by muse, mutect2, varscan2
- ENG | c.1678C>G p.Q560E | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.149); catalogued as CM050586, COSV100785268; called by muse, mutect2, varscan2
- EXPH5 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV56198909; called by muse, mutect2, varscan2
- FBN2 | c.8114C>A p.P2705H | Missense Mutation (SNP) | VAF 108/424 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52539840; called by muse, mutect2, varscan2
- FRMPD2 | c.2648C>T p.T883I | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as COSV59723435; called by muse, mutect2, varscan2
- GABRA3 | c.1468C>A p.R490S | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.066); catalogued as COSV64794720; called by muse, mutect2, varscan2
- GRIK5 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99489937; called by muse, mutect2, varscan2
- GRM2 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs1365229369; called by muse, varscan2
- HRNR | c.1548C>G p.S516R | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV64259774; called by muse, mutect2
- IARS2 | c.1606C>A p.H536N | Missense Mutation (SNP) | VAF 33/377 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs1299955084, COSV56964315; called by muse, mutect2
- IER3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1489268996; called by muse, mutect2, varscan2
- IFI16 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 50/440 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV55532876; called by mutect2, varscan2
- IGFBP2 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 133/414 reads (32%) | catalogued as COSV52080535; called by muse, mutect2, varscan2
- IGHV2-5 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs782068483; called by muse, mutect2, varscan2
- IL11 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52773536; called by muse, mutect2
- IRF6 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 161/484 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as CM092321, COSV65419083; called by muse, mutect2, varscan2
- ITK | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 45/434 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs751083005; called by muse, mutect2, varscan2
- ITPRIPL1 | c.295G>A p.D99N (on ENST00000439118 / NM_001008949.3; = p.D107N on NM_178495.6) | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs369211145; called by muse, varscan2
- KCNH5 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59757775; called by mutect2, varscan2
- KCNK2 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 44/386 reads (11%) | catalogued as rs765168645; called by muse, mutect2, varscan2
- KDM5B | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99351025; called by muse, mutect2, varscan2
- KIF4B | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 178/498 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV70531618; called by muse, mutect2, varscan2
- KLLN | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 69/422 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs962216778, COSV64288439; called by muse, mutect2, varscan2
- KRT9 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 68/519 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs1218831432; called by muse, mutect2, varscan2
- LHX8 | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs753429679, COSV53955348; called by muse, mutect2, varscan2
- MAGEC1 | c.1681C>G p.P561A | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); catalogued as COSV53579808; called by muse, mutect2
- MCTP1 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs752810491; called by muse, mutect2, varscan2
- NAALADL1 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.067); catalogued as rs1277436890; called by muse, mutect2, varscan2
- NCCRP1 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 69/380 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs147663476, COSV59212772; called by muse, mutect2, varscan2
- NCKAP1L | c.2305G>T p.A769S | Missense Mutation (SNP) | VAF 56/436 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53210503; called by muse, mutect2, varscan2
- NEUROD4 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 13/463 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV54471013; called by muse, mutect2
- NF1 | c.7213A>G p.I2405V (on ENST00000358273 / NM_001042492.3; = p.I2384V on NM_000267.3) | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs565708398, COSV62194004; ClinVar: uncertain significance; called by muse, varscan2
- NOS1AP | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 29/479 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV62639112; called by muse, mutect2
- OR4K17 | c.906G>C p.W302C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100210695; called by muse, mutect2, varscan2
- OR51B2 | c.508C>G p.H170D | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60916027; called by muse, mutect2, varscan2
- PCDH18 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 49/351 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV61266672, COSV61268906; called by muse, mutect2, varscan2
- PCDH18 | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 47/322 reads (15%) | catalogued as COSV61270126; called by mutect2, varscan2
- PHKB | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.84); catalogued as COSV54515097; called by muse, mutect2, varscan2
- PITPNM1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 58/350 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV62708361; called by muse, mutect2, varscan2
- PJA1 | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64053589; called by muse, mutect2, varscan2
- PRB1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 81/480 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as rs1436944876, COSV53706037; called by muse, mutect2, varscan2
- PSG2 | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 10/241 reads (4%) | catalogued as rs1289480592; called by muse, mutect2
- PTPN11 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 14/399 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104418174; called by muse, mutect2
- PZP | c.3443G>A p.S1148N | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as rs1279642033; called by muse, mutect2, varscan2
- RCE1 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.637); catalogued as COSV58992701; called by muse, mutect2
- RWDD4 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759832355; called by muse, mutect2, varscan2
- RYR2 | c.3244G>T p.G1082W | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV63679863; called by muse, mutect2, varscan2
- SDCCAG8 | c.808del p.L270Ffs*15 | Frame Shift Del (DEL) | VAF 46/278 reads (17%) | catalogued as COSV59405067; called by mutect2, varscan2
- SENP5 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.333); catalogued as rs780858586; called by muse, mutect2, varscan2
- SFMBT2 | c.2146G>T p.G716W | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV62810538; called by muse, mutect2, varscan2
- SLC22A11 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs751943384; called by muse, mutect2, varscan2
- SLC2A4RG | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99829384; called by muse, mutect2, varscan2
- SLC49A4 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 79/446 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1457487286; called by muse, mutect2, varscan2
- SND1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 45/333 reads (14%) | catalogued as COSV61241626; called by muse, mutect2, varscan2
- SOCS6 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV101205711, COSV67546221; called by muse, mutect2, varscan2
- SPTBN1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 64/492 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs1467998194, COSV61689753; called by muse, mutect2, varscan2
- STAG1 | c.1257G>T p.L419F | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.411); catalogued as COSV99366349; called by muse, mutect2, varscan2
- THEM6 | c.170C>G p.S57W | Missense Mutation (SNP) | VAF 304/721 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1563820547; called by muse, mutect2
- TIAM2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 51/360 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as COSV59692856; called by muse, mutect2, varscan2
- UGT2B4 | c.1389G>T p.W463C | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100522349; called by muse, mutect2, varscan2
- USH2A | c.14798A>T p.Q4933L | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as rs761954201; called by muse, mutect2, varscan2
- XIRP2 | c.3854C>T p.T1285I (on ENST00000628543; = p.T1460I on NM_152381.6) | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV54741657; called by muse, mutect2
- ZNF219 | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 13/426 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV53878840, COSV53884509; called by muse, mutect2
- ZNF496 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 312/612 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1391349068, COSV54181412; called by muse, mutect2, varscan2
- ZNF574 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs772200753; called by muse, mutect2, varscan2
- ZNF728 | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs557869573; called by muse, mutect2, varscan2
- ZNF737 | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV101417733; called by muse, mutect2, varscan2
- AGL | c.3542G>C p.R1181T | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGMO | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- AICDA | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPTL6 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ANKRD31 | c.2257G>T p.V753F | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ANKRD44 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 38/640 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- APC | c.1666G>C p.D556H | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ARHGAP28 | c.817G>T p.D273Y (on ENST00000383472 / NM_001366230.1; = p.D114Y on NM_001010000.3) | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASXL3 | c.3287C>A p.T1096K | Missense Mutation (SNP) | VAF 67/335 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ASXL3 | c.5081C>A p.P1694Q | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); called by muse, varscan2
- ATG9B | c.2028T>A p.D676E | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- ATP11C | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- BAZ2A | c.1198C>G p.Q400E | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- BMS1 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- BRINP2 | c.1335C>A p.C445* | Nonsense Mutation (SNP) | VAF 63/359 reads (18%) | called by muse, mutect2, varscan2
- C1orf115 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 232/467 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1D | c.4455C>G p.F1485L (on ENST00000350061 / NM_001128840.3; = p.F1505L on NM_000720.4) | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CCDC168 | c.7398G>T p.M2466I | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CCL27 | c.100T>A p.C34S | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK13 | c.3524C>T p.A1175V | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CELF2 | c.1230G>C p.Q410H (on ENST00000416382 / NM_001025077.3; = p.Q423H on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CENPF | c.3802G>A p.A1268T | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL3A1 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 82/323 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CROCC | c.2431del p.A811Rfs*26 | Frame Shift Del (DEL) | VAF 32/272 reads (12%) | called by mutect2, varscan2
- CSN3 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CYB5D2 | c.212G>T p.R71M | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DHX8 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 107/411 reads (26%) | called by muse, mutect2, varscan2
- DLG3 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH5 | c.2453A>C p.D818A | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAI1 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK7 | c.5642A>G p.Y1881C (on ENST00000635253 / NM_001367561.1; = p.Y1850C on NM_033407.3) | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DROSHA | c.3086A>G p.D1029G | Missense Mutation (SNP) | VAF 172/501 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- EMILIN1 | c.2764A>T p.T922S | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EML5 | c.352G>T p.G118* | Nonsense Mutation (SNP) | VAF 25/193 reads (13%) | called by muse, mutect2, varscan2
- ERVW-1 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 84/455 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EVX1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FAM13C | c.829T>C p.C277R | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- FAM168B | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2
- FAM83A | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 218/422 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FAT4 | c.14542G>T p.E4848* | Nonsense Mutation (SNP) | VAF 63/265 reads (24%) | called by muse, mutect2, varscan2
- FBLN2 | c.1743G>T p.E581D | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FEM1A | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSCN3 | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- GABRG2 | c.927C>G p.S309R (on ENST00000361925 / NM_001375343.1; = p.S269R on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GDA | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GEN1 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 52/374 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GIP | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- GIPC3 | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GIPC3 | c.1916C>G p.S639C | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GRID1 | c.2466C>G p.D822E | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GRIK5 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIN2D | c.1686C>A p.S562R | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIP2 | c.2632del p.D878Tfs*41 (on ENST00000619221; = p.D781Tfs*41 on NM_001080423.4) | Frame Shift Del (DEL) | VAF 88/400 reads (22%) | called by mutect2, varscan2
- GSR | c.1568G>T p.*523Lext*13 | Nonstop Mutation (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- HABP4 | c.1149G>T p.R383S | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- HIPK3 | c.1397del p.Y466Sfs*9 | Frame Shift Del (DEL) | VAF 28/180 reads (16%) | called by mutect2, varscan2
- HNF1A | c.1658C>A p.S553Y | Missense Mutation (SNP) | VAF 90/486 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSF1 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 39/740 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- IGFN1 | c.3395G>T p.W1132L (on ENST00000295591 / NM_001367841.1; = p.W3589L on NM_001164586.2) | Missense Mutation (SNP) | VAF 39/388 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- IMMP1L | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- INPP5J | c.1894G>T p.D632Y (on ENST00000331075 / NM_001284285.2; = p.D264Y on NM_001002837.2) | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR2 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 48/298 reads (16%) | called by muse, mutect2, varscan2
- KAT14 | c.1422G>T p.R474S | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KBTBD7 | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 66/399 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- KCNK9 | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 46/566 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- KIAA0825 | c.2839G>C p.E947Q | Missense Mutation (SNP) | VAF 11/390 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- KIRREL2 | c.1993C>A p.P665T | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- LYPD5 | c.208G>T p.V70L (on ENST00000377950 / NM_001031749.3; = p.V27L on NM_182573.2) | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- LZTFL1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAGEL2 | c.362A>G p.Q121R | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- MROH2A | c.2472C>G p.F824L | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, varscan2
- MXD3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- NAMPT | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NBEA | c.6046G>T p.E2016* | Nonsense Mutation (SNP) | VAF 44/259 reads (17%) | called by muse, mutect2, varscan2
- NKD2 | c.893G>T p.R298M | Missense Mutation (SNP) | VAF 111/353 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOL11 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, varscan2
- NPY1R | c.624G>T p.R208S | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- NUP210L | c.3124G>A p.D1042N | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- OR11L1 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- OR2AJ1 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2H1 | c.559T>A p.C187S | Missense Mutation (SNP) | VAF 89/506 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR2M5 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 288/577 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- OR4P4 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6N2 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 120/317 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- OVCH1 | c.1344G>T p.W448C | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PARD3 | c.2077C>A p.P693T | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PATZ1 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 71/414 reads (17%) | called by muse, mutect2, varscan2
- PCDH17 | c.2024C>A p.A675E | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PCDHGC4 | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 17/585 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PINK1 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 92/522 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PLPPR4 | c.1951G>C p.A651P | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNMA6F | c.1726C>A p.P576T | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- POGZ | c.2664A>T p.K888N | Missense Mutation (SNP) | VAF 142/406 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRAMEF10 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PRKD1 | c.2057T>C p.L686S | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PSME4 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 23/518 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- PTPDC1 | c.1610C>G p.S537C (on ENST00000375360 / NM_177995.3; = p.S589C on NM_152422.4) | Missense Mutation (SNP) | VAF 79/412 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- RDH12 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- RGL4 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2
- RP1 | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 11/318 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2
- RXFP4 | c.851A>T p.Y284F | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SCAF1 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, varscan2
- SCART1 | c.1731G>T p.W577C | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SECISBP2L | c.1822G>C p.D608H (on ENST00000559471 / NM_001193489.2; = p.D563H on NM_014701.4) | Missense Mutation (SNP) | VAF 64/402 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- SEMA5A | c.2063G>C p.G688A | Missense Mutation (SNP) | VAF 101/312 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SIRPA | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SLC13A4 | c.1230C>G p.Y410* | Nonsense Mutation (SNP) | VAF 46/220 reads (21%) | called by muse, mutect2, varscan2
- SLC39A10 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 59/406 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SLCO2B1 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SMYD1 | c.44A>T p.E15V | Missense Mutation (SNP) | VAF 58/490 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SOWAHC | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- SRCAP | c.8855G>T p.G2952V | Missense Mutation (SNP) | VAF 83/408 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- STRA8 | c.629T>A p.L210Q (on ENST00000275764; = p.L188Q on NM_182489.2) | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- SYT10 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TANC2 | c.3998G>T p.R1333M | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TJP3 | c.2359C>T p.H787Y | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TMEM215 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TNC | c.4487C>T p.S1496L | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TRIM47 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- TRPM7 | c.5309G>T p.G1770V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSEN34 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- UBE2J2 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 70/465 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UPF3B | c.1435G>C p.E479Q (on ENST00000276201 / NM_080632.3; = p.E466Q on NM_023010.3) | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2
- USH2A | c.463A>C p.K155Q | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- YIPF1 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H13 | c.2752G>C p.D918H | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ZNF251 | c.261G>C p.L87F | Missense Mutation (SNP) | VAF 68/712 reads (10%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF41 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 13/235 reads (6%) | called by muse, mutect2
- ZNF540 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF658 | c.2467G>T p.E823* | Nonsense Mutation (SNP) | VAF 35/211 reads (17%) | called by muse, mutect2, varscan2
- ZYX | c.651G>C p.Q217H | Missense Mutation (SNP) | VAF 26/644 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- ABCA8 | c.4170G>A p.L1390= | Silent (SNP) | VAF 49/410 reads (12%) | called by muse, mutect2, varscan2
- ACTL6B | c.897C>T p.L299= | Silent (SNP) | VAF 36/201 reads (18%) | called by muse, mutect2, varscan2
- ADAD2 | c.999C>T p.V333= (on ENST00000315906 / NM_001145400.2; = p.V415= on NM_139174.4) | Silent (SNP) | VAF 16/456 reads (4%) | called by muse, mutect2
- ARHGAP15 | c.426A>G p.A142= | Silent (SNP) | VAF 137/543 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.630G>C p.R210= | Silent (SNP) | VAF 64/219 reads (29%) | called by muse, mutect2, varscan2
- BBS9 | c.540G>T p.L180= | Silent (SNP) | VAF 107/415 reads (26%) | called by muse, mutect2, varscan2
- BCAS3 | c.2202C>T p.P734= (on ENST00000390652 / NM_001353144.2; = p.P719= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/297 reads (10%) | catalogued as rs758111943; called by muse, mutect2, varscan2
- BFAR | c.27G>A p.V9= | Silent (SNP) | VAF 52/302 reads (17%) | catalogued as rs779360966; called by muse, mutect2, varscan2
- BICC1 | c.2199G>A p.Q733= | Silent (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- BTBD11 | c.1647C>T p.A549= (on ENST00000280758 / NM_001018072.2; = p.A86= on NM_001017523.2) | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as rs777195666; called by muse, mutect2, varscan2
- CD1E | c.231G>A p.L77= | Silent (SNP) | VAF 99/500 reads (20%) | catalogued as COSV63773282; called by muse, mutect2, varscan2
- CDH8 | c.1098C>T p.F366= | Silent (SNP) | VAF 70/430 reads (16%) | called by muse, mutect2, varscan2
- CEACAM19 | c.591G>A p.R197= | Silent (SNP) | VAF 38/246 reads (15%) | catalogued as rs1372414914; called by muse, mutect2, varscan2
- CEP85 | c.711G>T p.R237= | Silent (SNP) | VAF 73/422 reads (17%) | catalogued as rs748406698; called by muse, mutect2, varscan2
- CHRM3 | c.261C>A p.I87= | Silent (SNP) | VAF 76/354 reads (21%) | catalogued as rs754466236; called by muse, mutect2, varscan2
- CHST2 | c.1215G>T p.T405= | Silent (SNP) | VAF 49/264 reads (19%) | catalogued as COSV58887013; called by muse, mutect2, varscan2
- CMYA5 | c.4614G>A p.K1538= | Silent (SNP) | VAF 45/336 reads (13%) | catalogued as rs1561208871; called by muse, mutect2, varscan2
- COLGALT1 | c.222C>G p.L74= | Silent (SNP) | VAF 18/302 reads (6%) | catalogued as rs1427261741; called by muse, mutect2
- CUL3 | c.321A>G p.Q107= | Silent (SNP) | VAF 33/258 reads (13%) | called by muse, mutect2, varscan2
- DCHS1 | c.1914G>C p.V638= | Silent (SNP) | VAF 72/427 reads (17%) | called by muse, mutect2, varscan2
- DDX19A | c.1143C>G p.G381= | Silent (SNP) | VAF 56/354 reads (16%) | called by muse, mutect2, varscan2
- DLGAP3 | c.1278C>T p.T426= | Silent (SNP) | VAF 52/299 reads (17%) | called by muse, mutect2, varscan2
- DRD2 | c.165G>T p.V55= | Silent (SNP) | VAF 95/507 reads (19%) | called by muse, mutect2, varscan2
- EDNRB | c.336G>A p.S112= (on ENST00000377211 / NM_001201397.1; = p.S22= on NM_000115.5) | Silent (SNP) | VAF 51/372 reads (14%) | catalogued as COSV57521197; called by muse, mutect2, varscan2
- FAM110D | c.258C>T p.F86= | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- GTF2E2 | c.339C>G p.L113= | Silent (SNP) | VAF 34/173 reads (20%) | called by muse, varscan2
- HAPLN1 | c.342G>C p.L114= | Silent (SNP) | VAF 82/340 reads (24%) | called by muse, mutect2, varscan2
- HOXD11 | c.570C>T p.F190= | Silent (SNP) | VAF 17/318 reads (5%) | called by muse, mutect2
- HSF1 | c.375G>A p.L125= | Silent (SNP) | VAF 38/656 reads (6%) | catalogued as rs782221015, COSV101275173; called by muse, mutect2
- ID1 | c.402C>T p.G134= | Silent (SNP) | VAF 108/491 reads (22%) | called by muse, mutect2, varscan2
- IDUA | c.1161C>A p.L387= | Silent (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- IFNA16 | c.399C>T p.A133= | Silent (SNP) | VAF 60/212 reads (28%) | catalogued as rs1241845133; called by muse, mutect2, varscan2
- ITLN2 | c.261G>T p.G87= | Silent (SNP) | VAF 169/518 reads (33%) | called by muse, mutect2, varscan2
- KRTAP24-1 | c.753G>A p.L251= | Silent (SNP) | VAF 22/174 reads (13%) | catalogued as COSV61090125; called by muse, mutect2, varscan2
- LCE1E | c.159C>T p.G53= | Silent (SNP) | VAF 54/448 reads (12%) | catalogued as rs756254791; called by muse, mutect2, varscan2
- LHX1 | c.771G>C p.R257= | Silent (SNP) | VAF 16/546 reads (3%) | called by muse, mutect2
- LRIT2 | c.765C>A p.I255= | Silent (SNP) | VAF 47/325 reads (14%) | called by muse, mutect2, varscan2
- LRRC7 | c.2829T>C p.L943= (on ENST00000651989 / NM_001370785.2; = p.L910= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 50/314 reads (16%) | called by muse, mutect2, varscan2
- MBD6 | c.1344G>T p.G448= | Silent (SNP) | VAF 54/443 reads (12%) | called by muse, mutect2, varscan2
- MCM2 | c.735C>T p.A245= | Silent (SNP) | VAF 73/313 reads (23%) | called by muse, mutect2, varscan2
- MPC2 | c.120A>T p.T40= | Silent (SNP) | VAF 26/141 reads (18%) | called by muse, mutect2, varscan2
- MRC1 | c.3981T>C p.G1327= | Silent (SNP) | VAF 73/396 reads (18%) | catalogued as rs1200579055; called by muse, mutect2, varscan2
- MYO16 | c.3843C>T p.F1281= | Silent (SNP) | VAF 18/476 reads (4%) | catalogued as COSV62764356; called by muse, mutect2
- NCAM1 | c.1413C>T p.A471= (on ENST00000316851 / NM_181351.5; = p.A461= on NM_000615.7) | Silent (SNP) | VAF 22/174 reads (13%) | catalogued as COSV57519869, COSV57522164; called by muse, mutect2, varscan2
- NIPAL1 | c.1023G>T p.L341= | Silent (SNP) | VAF 42/233 reads (18%) | catalogued as COSV55006328; called by muse, mutect2, varscan2
- NPAS4 | c.1470T>A p.T490= | Silent (SNP) | VAF 81/418 reads (19%) | called by muse, mutect2, varscan2
- NRG1 | c.849G>T p.R283= (on ENST00000405005 / NM_013964.5; = p.R288= on NM_013956.5) | Silent (SNP) | VAF 138/380 reads (36%) | called by mutect2, varscan2
- NUDT12 | c.1386C>G p.L462= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- NUTM2D | c.771C>A p.V257= | Silent (SNP) | VAF 24/494 reads (5%) | called by muse, mutect2
- OGDHL | c.1068G>T p.S356= | Silent (SNP) | VAF 59/347 reads (17%) | catalogued as rs562281972, COSV65104016; called by muse, mutect2, varscan2
- OR2M7 | c.273C>A p.S91= | Silent (SNP) | VAF 214/463 reads (46%) | catalogued as COSV100522594; called by muse, mutect2, varscan2
- OR2T5 | c.54C>A p.L18= | Silent (SNP) | VAF 192/600 reads (32%) | catalogued as COSV63540469; called by muse, varscan2
- OR4S2 | c.282G>T p.G94= | Silent (SNP) | VAF 68/416 reads (16%) | called by muse, mutect2
- PAX7 | c.1218C>A p.I406= | Silent (SNP) | VAF 49/312 reads (16%) | called by muse, mutect2, varscan2
- PEAK1 | c.4659G>A p.V1553= | Silent (SNP) | VAF 30/254 reads (12%) | called by muse, mutect2, varscan2
- PLXND1 | c.981C>T p.A327= | Silent (SNP) | VAF 61/324 reads (19%) | catalogued as rs1397305347; called by muse, mutect2, varscan2
- PNKD | c.1113C>G p.L371= | Silent (SNP) | VAF 15/461 reads (3%) | catalogued as COSV99282127; called by muse, mutect2
- PORCN | c.573G>A p.Q191= | Silent (SNP) | VAF 11/175 reads (6%) | catalogued as COSV58226200; called by muse, mutect2
- PRKAR1A | c.1053C>T p.D351= | Silent (SNP) | VAF 58/925 reads (6%) | catalogued as rs750774049; called by muse, mutect2
- RNF14 | c.888C>G p.L296= | Silent (SNP) | VAF 13/418 reads (3%) | catalogued as COSV100641262; called by muse, mutect2
- RTL1 | c.1632A>T p.L544= | Silent (SNP) | VAF 48/296 reads (16%) | called by muse, mutect2, varscan2
- RYR3 | c.11989T>C p.L3997= (on ENST00000389232; = p.L3998= on NM_001036.6) | Silent (SNP) | VAF 82/315 reads (26%) | catalogued as rs1377742527, COSV66779225; called by muse, mutect2, varscan2
- SECISBP2 | c.1947C>G p.L649= | Silent (SNP) | VAF 16/434 reads (4%) | called by muse, mutect2
- SETBP1 | c.2616G>A p.G872= | Silent (SNP) | VAF 61/422 reads (14%) | called by muse, mutect2, varscan2
- SHROOM3 | c.5682G>A p.L1894= | Silent (SNP) | VAF 42/274 reads (15%) | catalogued as rs1293053602; called by muse, mutect2, varscan2
- SIX3 | c.261C>T p.F87= | Silent (SNP) | VAF 24/271 reads (9%) | catalogued as rs1279186542; called by muse, mutect2
- SLC25A52 | c.873C>T p.I291= (on ENST00000672005; = p.I281= on NM_001034172.4) | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as rs1202629150; called by muse, varscan2
- SLC2A4RG | c.237G>A p.A79= | Silent (SNP) | VAF 42/228 reads (18%) | called by muse, varscan2
- SLC35B2 | c.816C>T p.L272= | Silent (SNP) | VAF 63/415 reads (15%) | called by muse, mutect2, varscan2
- SUCNR1 | c.201C>A p.V67= | Silent (SNP) | VAF 55/297 reads (19%) | called by muse, mutect2, varscan2
- SVOP | c.513C>T p.P171= | Silent (SNP) | VAF 63/420 reads (15%) | catalogued as rs149268005, COSV54469765; called by muse, mutect2, varscan2
- SYCE1L | c.606C>T p.F202= | Silent (SNP) | VAF 13/357 reads (4%) | catalogued as rs1026941581; called by muse, mutect2
- SYNE2 | c.657C>T p.I219= | Silent (SNP) | VAF 45/303 reads (15%) | called by muse, mutect2, varscan2
- SZT2 | c.2250C>T p.L750= | Silent (SNP) | VAF 54/246 reads (22%) | catalogued as rs768167577; called by muse, mutect2, varscan2
- TET1 | c.4524C>T p.H1508= | Silent (SNP) | VAF 55/362 reads (15%) | called by muse, mutect2, varscan2
- THEM6 | c.237C>G p.V79= | Silent (SNP) | VAF 309/695 reads (44%) | called by muse, mutect2
- TIGD3 | c.852C>G p.L284= | Silent (SNP) | VAF 40/352 reads (11%) | catalogued as COSV52888752; called by muse, mutect2, varscan2
- TMED9 | c.330C>T p.F110= | Silent (SNP) | VAF 60/492 reads (12%) | called by muse, mutect2, varscan2
- TMEM121 | c.747C>T p.F249= | Silent (SNP) | VAF 12/276 reads (4%) | catalogued as rs1555444307; called by muse, mutect2
- TRBV28 | c.297C>A p.S99= | Silent (SNP) | VAF 51/282 reads (18%) | called by muse, mutect2, varscan2
- TXNDC11 | c.330C>A p.L110= | Silent (SNP) | VAF 68/374 reads (18%) | called by muse, mutect2, varscan2
- UPK1B | c.132C>T p.Y44= | Silent (SNP) | VAF 59/381 reads (15%) | catalogued as COSV51767436; called by muse, mutect2, varscan2
- WDFY3 | c.3243G>T p.G1081= | Silent (SNP) | VAF 28/222 reads (13%) | called by muse, mutect2, varscan2
- ZNF329 | c.1602G>C p.L534= | Silent (SNP) | VAF 41/244 reads (17%) | called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.816C>A p.P272= | Silent (SNP) | VAF 45/194 reads (23%) | called by muse, varscan2
- DHX30 | c.125-2254G>A | Intron (SNP) | VAF 45/262 reads (17%) | catalogued as rs1217398581; called by muse, mutect2, varscan2
- LINC00960 | chr3:75679008 G>A | 3'Flank (SNP) | VAF 55/373 reads (15%) | called by muse, mutect2, varscan2
- PIGG | c.-1G>C | 5'UTR (SNP) | VAF 36/171 reads (21%) | catalogued as rs782195633; called by muse, mutect2, varscan2
